Gene-level copy-number profile of tumor specimen TCGA-GN-A4U3-06A from TCGA case TCGA-GN-A4U3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 37.0 years (13,524 days).
Specimen TCGA-GN-A4U3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.470be9bb-4765-40db-9e83-5ea167718f31.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GN-A4U3-10F (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc30e2f4-ca10-41d9-a8dd-7ede355f2b03

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,504; copy number 2: 14,663; copy number 3: 13,058; copy number 4: 20,892; copy number 5: 8,964; copy number 6: 707; copy number 7: 6; copy number 12: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GN-A4U3-06A-11D-A32M-01): tumor purity 0.85, ploidy 3.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:61,143,656–62,078,335, 5 genes, copy number 12 (within-gene range 7–12): LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1.

Autosomal genes at a single copy (total copy number 1): 33. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
